Somatic mutation profile of tumor specimen 0DGBB5 from CCDI case PBBPBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,861 days).
Specimen 0DGBB5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a2147c-c48e-40cb-a16a-a5b741fa9a0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG9FU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b016a2a-5e13-4845-8a41-013b132c01f4

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMCN2 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 56/886 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782305604; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 61/1498 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DSTN | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 53/1513 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ENO2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 60/1354 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); called by muse, mutect2
- TNKS1BP1 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 44/1064 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFPM2 | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 30/1142 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 30/939 reads (3%) | called by muse, mutect2
